Gene-level copy-number profile of tumor specimen TCGA-LN-A49S-01A from TCGA case TCGA-LN-A49S, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 59.9 years (21,865 days).
Specimen TCGA-LN-A49S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.0ffaf13d-040c-477e-8e3c-57ca235c65bc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9af1ff77-d2d3-40a3-b383-dc7951cc060a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 7,580; copy number 2: 25,677; copy number 3: 13,677; copy number 4: 10,652; copy number 5: 1,302; copy number 6: 628; copy number 7: 214; copy number 8: 68; copy number 10: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A49S-01A-11D-A246-01): tumor purity 0.37, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–22,128,103, 8 genes (within-gene range 0–1): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,222 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,361,922–44,390,823, 105 genes, copy number 5 (broad region; genes not listed).
- chr1:169,662,007–169,854,080, 1 gene, copy number 5 (within-gene range 4–5): C1orf112.
- chr1:169,722,640–180,278,984, 205 genes, copy number 5–7 (broad region; genes not listed).
- chr4:33,433,510–34,335,351, 7 genes, copy number 5: AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1, LINC02484, AC110790.1.
- chr6:37,815,777–42,693,505, 102 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:45,880,827–63,616,361, 224 genes, copy number 5 (broad region; genes not listed).
- chr6:128,883,138–129,516,566, 1 gene, copy number 6 (within-gene range 2–6): LAMA2.
- chr6:129,157,523–131,628,242, 23 genes, copy number 6: BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA, AL583803.1, SMLR1, EPB41L2, AKAP7, AL137222.1, RPL21P67, ARG1, MED23.
- chr6:131,642,818–131,642,966, 1 gene, copy number 6: RNU4-18P.
- chr6:167,767,083–170,738,536, 72 genes, copy number 5 (broad region; genes not listed).
- chr7:26,398,593–34,299,012, 177 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:81,489,204–81,770,438, 3 genes, copy number 6 (within-gene range 2–6): AC008163.1, DDX43P3, HGF.
- chr7:82,009,177–82,029,955, 1 gene, copy number 6: CACNA2D1-AS1.
- chr7:84,528,122–86,217,733, 13 genes, copy number 6: RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1.
- chr8:19,375,128–20,700,152, 16 genes, copy number 5: AC068880.4, CSGALNACT1, AC090541.1, INTS10, LPL, AC100802.1, RPL30P9, SLC18A1, ATP6V1B2, RNU6-892P, LZTS1, LZTS1-AS1, RNA5SP257, AC023403.1, AC022559.1, AC018541.1.
- chr8:33,436,268–40,901,854, 135 genes, copy number 5–8 (broad region; genes not listed).
- chr8:103,140,713–103,298,772, 2 genes, copy number 5 (within-gene range 4–5): BAALC, BAALC-AS1.
- chr8:103,228,425–138,083,657, 400 genes, copy number 5 (broad region; genes not listed).
- chr11:34,430,880–40,112,599, 59 genes, copy number 6–10: CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1, AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1.
- chr12:44,880,868–48,496,524, 103 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr12:48,487,946–48,488,408, 1 gene, copy number 5: RPS10P20.
- chr16:77,788,564–77,980,107, 1 gene, copy number 7 (within-gene range 4–7): VAT1L.
- chr16:77,892,422–78,066,761, 5 genes, copy number 7: PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr16:78,123,243–78,275,607, 4 genes, copy number 7: AC079414.3, AC009044.1, WWOX-AS1, AC106743.1.
- chr16:89,613,308–90,222,851, 33 genes, copy number 7: DPEP1, CHMP1A, SPATA33, AC010538.1, CDK10, LINC02166, SPATA2L, VPS9D1, VPS9D1-AS1, ZNF276, FANCA, SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr18:47,390–15,330,282, 376 genes, copy number 6–7 (broad region; genes not listed).
- chr20:34,689,097–39,349,392, 152 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,114. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
